Somatic mutation profile of tumor specimen TARGET-30-PASAJU-01A (aliquot TARGET-30-PASAJU-01A-01D) from TARGET case TARGET-30-PASAJU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.9 years (2,140 days).
Specimen TARGET-30-PASAJU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eabfbaf-755c-471f-b7d1-0c929fbf7e1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASAJU-10A (Blood Derived Normal), aliquot TARGET-30-PASAJU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/935db87a-d73c-44b6-a39c-d034e41451d9

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL3 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.886); catalogued as rs1464010662; called by muse, mutect2
- CACNB3 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs763868992; called by muse, mutect2, varscan2
- DNAI3 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54004031; called by muse, mutect2, varscan2
- HROB | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55370112; called by muse, mutect2, varscan2
- KIF16B | c.1392G>T p.L464F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61709076; called by muse, mutect2, varscan2
- OPA3 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); catalogued as rs371832021; called by muse, mutect2, varscan2
- OR2A12 | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68821698; called by muse, mutect2, varscan2
- PMFBP1 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 38/134 reads (28%) | catalogued as COSV52827226; called by muse, mutect2, varscan2
- ZNF574 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55905108; called by muse, mutect2, varscan2
- ZNF585A | c.1156G>A p.D386N (on ENST00000292841 / NM_001288800.2; = p.D331N on NM_152655.3) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53065138; called by muse, mutect2, varscan2
- BCAS1 | c.965del p.K322Sfs*31 | Frame Shift Del (DEL) | VAF 16/202 reads (8%) | called by mutect2, pindel
- C4BPA | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- AHNAK2 | c.4092C>T p.L1364= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs1484144288, COSV60917546; called by muse, varscan2
- IGKV6-21 | c.231C>T p.V77= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs771310819; called by muse, mutect2, varscan2
- KCNK10 | c.1287G>A p.E429= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV56647833; called by muse, mutect2, varscan2
